Surgical pathology report (de-identified scan), TCGA case TCGA-VQ-A8PX, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VQ-A8PX-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

ICD-6 3
Adenocarcinoma, intestinal
type 8144/3
Stomach NOS C16.9
JW 3/7/14

PATHOLOGY REPORT:

PRIMARY SITE: Stomach (Gastric stump)

"Product of total gastrectomy + D1 lymphadenectomy + celiac trunk":

- . Invasive moderately differentiated adenocarcinoma, intestinal pattern Lauren (greater lesion)
- . Tumor size: 1.5 cm
- . Depth of infiltration: neoplasia confined to the mucosa and lamina propria
- . Blood vascular invasion: not detected
- . Lymphatic vascular invasion: not detected
- . Perineural invasion: not detected
- . Smaller lesion (0.5 cm): fundic gland polyp with reactive reparative cytological foveolar alterations.
- . Adjacent gastric mucosa: active chronic moderate gastritis with glandular dilatation and reactive / reparative cytological foveolar alterations
- . Intestinal mucosa: within normal limits
- . Surgical margins uninvolved by neoplasia
- . 24 perigastric lymph nodes were dissected, all uninvolved by neoplasia (0/24), thus distributed:
- Right paracardic: 0/4
- Left paracardic: 0/2
- Short gastrics: 0/0
- Right gastroepiploic: 0/0
- Left Gastric Artery: 0/0
- Anterior hepatic artery: 0/8
- Celiac trunk: 0/7
- Splenic lymph node: 0/2
- Hepatogastric ligament: 0/1

"Esophageal margin":

- . Absence of neoplasia

"Gallbladder (cholecystectomy product)":

- . Discrete chronic cholecystitis

"Spleen (splenectomy product)":

- . Within normal limits
- . Absence of neoplastic infiltration

Hist/AA Discrepancy		☒
Primary Malignancy History		☒

Source: NCI Genomic Data Commons file b158711f-f9f0-4c15-a43e-c0460adf5278 (TCGA-VQ-A8PX.958101B1-4A0A-4760-9BC7-036CE3A2E321.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).